CCDI case PBCPXK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/239508ed-e262-4eb4-a3e1-ec495a9ef3d7

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.3 years (4,843 days).

Biospecimens (3 samples)
- Sample 0DX8JQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX8JS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX8KJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
